Somatic mutation profile of tumor specimen TCGA-2G-AAHL-01A (aliquot TCGA-2G-AAHL-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAHL, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 26.7 years (9,749 days).
Specimen TCGA-2G-AAHL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c85c3f78-a5e2-4406-9d3d-3312e906df28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAHL-10A (Blood Derived Normal), aliquot TCGA-2G-AAHL-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/642863f0-49ff-476b-92d0-75bf78dc22eb

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2466T>G p.N822K | Missense Mutation (SNP) | VAF 97/126 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913514, COSV55387147, COSV55389584, COSV55431266; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GRAMD1B | c.1964C>G p.T655S | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs775623707; called by muse, mutect2, varscan2
- ABCF2 | c.489G>A p.M163I | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ADAMTS5 | c.2093G>C p.C698S | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CHST3 | c.1296G>A p.M432I | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF5B | c.1670G>A p.S557N | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- FARP2 | c.439G>C p.D147H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- GPR87 | c.910G>C p.A304P | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- GRM1 | c.2186C>G p.P729R | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MIER3 | c.1094G>C p.G365A (on ENST00000381199 / NM_001297599.2; = p.G364A on NM_152622.4) | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MTF2 | c.1196A>G p.K399R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PRRC1 | c.817G>C p.V273L | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- ZFC3H1 | c.2266A>T p.K756* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- COL1A2 | c.1545T>C p.L515= | Silent (SNP) | VAF 50/224 reads (22%) | called by muse, mutect2, varscan2
- GFRA3 | c.318C>A p.R106= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- NSD1 | c.2877A>T p.G959= | Silent (SNP) | VAF 47/159 reads (30%) | called by muse, mutect2, varscan2
- RNF26 | c.765C>G p.T255= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs752489469; called by muse, mutect2, varscan2
- SMARCB1 | c.363-2142C>A | Intron (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- YIF1A | c.735+21del | Intron (DEL) | VAF 4/30 reads (13%) | catalogued as rs750015700; called by pindel, varscan2
